Gene-level copy-number profile of tumor specimen TCGA-QK-A8ZA-01A from TCGA case TCGA-QK-A8ZA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 60.2 years (21,979 days).
Specimen TCGA-QK-A8ZA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a63a8eef-eac5-46a9-a63e-9b69ff6c503d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A8ZA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85900731-0e68-4e8d-9796-2a8d9a066376

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 243; copy number 2: 14,329; copy number 3: 11,608; copy number 4: 15,448; copy number 5: 7,549; copy number 6: 5,968; copy number 7: 953; copy number 8: 1,617; copy number 9: 673; copy number 10: 257; copy number 11: 263; copy number 12: 185; copy number 13: 87; copy number 14: 62; copy number 15: 11; copy number 16: 158; copy number 17: 2; copy number 18: 6; copy number 19: 15; copy number 20: 160; copy number 23: 12; copy number 24: 16; copy number 25: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A8ZA-01A-11D-A390-01): tumor purity 0.69, ploidy 3.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,167,357, 3 genes: LRRC57P1, Y_RNA, RNU6-904P.
- chr4:86,117,912–86,219,926, 1 gene (within-gene range 0–2): MAPK10-AS1.
- chr5:59,039,761–59,529,251, 3 genes: AC092343.1, AC008833.1, NDUFB4P2.
- chr5:93,617,725–94,111,699, 1 gene (within-gene range 0–2): FAM172A.
- chr5:93,860,669–94,176,029, 2 genes: AC114980.1, AC117528.1.
- chr5:94,877,599–94,980,893, 2 genes: AC008534.2, MCTP1-AS1.
- chr8:84,948,585–84,949,674, 1 gene: ACTBP6.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–2): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:131,373,636–131,500,197, 3 genes (within-gene range 0–8): PRRC2B, SNORD62A, SNORD62B.
- chr21:14,757,588–23,423,778, 112 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:29,351,634–29,376,339, 4 genes: BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,945 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:186,930,325–189,325,304, 29 genes, copy number 10–13 (within-gene range 6–13): ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1.
- chr3:189,631,389–189,897,276, 1 gene, copy number 13 (within-gene range 6–13): TP63.
- chr3:189,829,922–191,398,659, 21 genes, copy number 13 (within-gene range 7–13): MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50.
- chr3:192,729,555–197,651,482, 156 genes, copy number 9–10 (broad region; genes not listed).
- chr4:92,303,966–93,810,157, 1 gene, copy number 15 (within-gene range 5–15): GRID2.
- chr4:92,884,663–94,370,163, 10 genes, copy number 15: AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11.
- chr6:23,971,879–25,701,783, 45 genes, copy number 10–19 (within-gene range 6–19): AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2, CMAHP, AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P, AL022170.1, SCGN, PRELID1P2.
- chr6:44,727,921–56,954,649, 179 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr6:73,209,083–80,557,189, 114 genes, copy number 9–10 (broad region; genes not listed).
- chr6:82,892,390–83,065,841, 1 gene, copy number 24 (within-gene range 2–24): UBE3D.
- chr6:83,067,666–90,363,912, 129 genes, copy number 12–24 (broad region; genes not listed).
- chr6:96,521,595–97,283,217, 13 genes, copy number 9: UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L.
- chr6:97,710,953–97,717,197, 1 gene, copy number 9: AL080316.1.
- chr9:5,450,503–11,013,096, 60 genes, copy number 13–23: CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1.
- chr9:24,542,952–25,938,434, 8 genes, copy number 13: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr9:31,253,901–43,045,120, 381 genes, copy number 10–12 (broad region; genes not listed).
- chr11:69,294,151–80,327,911, 321 genes, copy number 16–25 (broad region; genes not listed).
- chr13:110,615,460–113,099,742, 43 genes, copy number 10–12 (within-gene range 2–12): NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1.
- chr14:24,573,518–33,804,176, 112 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr14:71,141,125–87,573,022, 276 genes, copy number 9–17 (within-gene range 8–17) (broad region; genes not listed).
- chr14:97,427,071–99,480,889, 23 genes, copy number 9 (within-gene range 8–9): LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1, C14orf177, AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.3, AL162151.1, BCL11B, AL109767.1, AL132819.1, SETD3, RNU6-91P.
- chr14:106,714,684–106,875,071, 21 genes, copy number 10: IGHV1-69, IGHV2-70D, IGHV3-69-1, IGHV1-69-2, AC245369.21, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.

Autosomal genes at a single copy (total copy number 1): 243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
